Somatic mutation profile of tumor specimen 0DUVTT from CCDI case PBCMBU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Pleura, NOS; Age at diagnosis: 16.9 years (6,187 days).
Specimen 0DUVTT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff105734-b7f6-4bc9-8dd3-2e3561d3ab21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUVT8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a479c5a5-07dc-4901-b9f8-e80b3180079c

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Intron 2, 3'UTR 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 224/519 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DKC1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 187/400 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV101059913; called by muse, mutect2, varscan2
- LRRCC1 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 259/616 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs370959283; called by muse, mutect2, varscan2
- ZNF8 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 175/642 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs748251226; called by muse, mutect2, varscan2
- A4GNT | c.129A>T p.E43D | Missense Mutation (SNP) | VAF 136/278 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP6 | c.1397C>A p.A466E | Missense Mutation (SNP) | VAF 264/583 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLQ | c.4801C>A p.H1601N | Missense Mutation (SNP) | VAF 222/496 reads (45%) | SIFT tolerated (0.85); PolyPhen benign (0.015); called by mutect2, varscan2
- REPS2 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 373/894 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- SAGE1 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 56/707 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- TRPV3 | c.1243-2A>G p.X415_splice | Splice Site (SNP) | VAF 220/483 reads (46%) | called by muse, mutect2, varscan2
- GALNT13 | c.1188A>C p.S396= | Silent (SNP) | VAF 166/597 reads (28%) | called by muse, mutect2, varscan2
- HPN | c.189C>T p.L63= | Silent (SNP) | VAF 250/747 reads (33%) | catalogued as rs769719048; called by muse, mutect2, varscan2
- CIAO3 | c.67-81G>T | Intron (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- IL1RN | c.*55C>T | 3'UTR (SNP) | VAF 57/181 reads (31%) | called by muse, mutect2, varscan2
- MRTFB | c.1079+309G>A | Intron (SNP) | VAF 170/402 reads (42%) | catalogued as rs374302345; called by muse, mutect2, varscan2
- PABPC1L2A | c.-57G>A | 5'UTR (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
